Somatic mutation profile of tumor specimen 0DV4J5 from CCDI case PBCMDF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,695 days).
Specimen 0DV4J5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 224242e5-3561-4149-94d0-1116c839f2ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV4IQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c61887f-e1a8-4754-b86b-db6885f6a5f8

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Intron 4, Nonsense Mutation 3, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM83B | c.708C>G p.C236W | Missense Mutation (SNP) | VAF 52/696 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333537578; called by muse, mutect2
- FANCA | c.2602-2A>G p.X868_splice | Splice Site (SNP) | VAF 19/630 reads (3%) | catalogued as CS991388; called by muse, mutect2
- GREB1 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 210/442 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as rs889402087, COSV52196294; called by muse, mutect2, varscan2
- GUCY2D | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 55/561 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs137853897, CM119880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LENEP | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 88/892 reads (10%) | catalogued as COSV52698119; called by muse, mutect2
- PCDH9 | c.285A>C p.E95D | Missense Mutation (SNP) | VAF 19/687 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60550210; called by muse, mutect2
- PDE6B | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 447/1088 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199768318, COSV55325135; called by muse, mutect2, varscan2
- ZNF341 | c.2083C>T p.R695C (on ENST00000375200 / NM_001282935.1; = p.R688C on NM_032819.4) | Missense Mutation (SNP) | VAF 317/762 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs764220500; called by muse, mutect2, varscan2
- B3GNT8 | c.1097A>T p.H366L | Missense Mutation (SNP) | VAF 73/684 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX9 | c.2165T>A p.I722K | Missense Mutation (SNP) | VAF 58/572 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- EBF3 | c.449T>A p.M150K | Missense Mutation (SNP) | VAF 81/761 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- FREM3 | c.3718C>T p.R1240* | Nonsense Mutation (SNP) | VAF 307/743 reads (41%) | called by muse, mutect2, varscan2
- MRS2 | c.432A>G p.I144M | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2
- P2RY8 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 312/663 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PIEZO1 | c.6863T>A p.M2288K | Missense Mutation (SNP) | VAF 19/714 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- PSMA6 | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 58/696 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPAG6 | c.127A>C p.M43L | Missense Mutation (SNP) | VAF 57/399 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAG1 | c.1827G>T p.M609I | Missense Mutation (SNP) | VAF 32/780 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2
- SUPT6H | c.3679G>A p.G1227S | Missense Mutation (SNP) | VAF 124/1594 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- THSD4 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 143/286 reads (50%) | called by muse, mutect2, varscan2
- ZNHIT1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 179/911 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CABP5 | c.99G>A p.L33= | Silent (SNP) | VAF 20/450 reads (4%) | called by muse, mutect2
- CDC27 | c.1863A>G p.L621= | Silent (SNP) | VAF 89/1279 reads (7%) | called by muse, mutect2
- FAM98C | c.204C>T p.S68= | Silent (SNP) | VAF 26/996 reads (3%) | called by muse, mutect2
- GUCY2F | c.3303G>A p.R1101= | Silent (SNP) | VAF 34/340 reads (10%) | called by muse, mutect2, varscan2
- HELZ2 | c.4750C>T p.L1584= (on ENST00000467148 / NM_001037335.2; = p.L1015= on NM_033405.3) | Silent (SNP) | VAF 42/444 reads (9%) | called by muse, mutect2
- MUC12 | c.4140C>T p.L1380= (on ENST00000379442; = p.L1237= on NM_001164462.1) | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as rs1204024262; called by muse, mutect2, varscan2
- SLC4A9 | c.1635C>T p.G545= (on ENST00000507527 / NM_001258428.2; = p.G521= on NM_031467.3) | Silent (SNP) | VAF 72/774 reads (9%) | catalogued as rs1393154078; called by muse, mutect2
- KDM5D | c.2339-35A>C | Intron (SNP) | VAF 54/236 reads (23%) | called by muse, mutect2, varscan2
- REEP1 | c.32+82C>A | Intron (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- TMC7 | c.-26G>A | 5'UTR (SNP) | VAF 59/197 reads (30%) | called by muse, mutect2, varscan2
- TMEM243 | c.129+83dup | Intron (INS) | VAF 70/294 reads (24%) | catalogued as rs1383115756; called by mutect2, varscan2
- VPS13C | c.10863+775C>G | Intron (SNP) | VAF 36/317 reads (11%) | catalogued as rs758316353; called by muse, mutect2, varscan2
